FM case AD9486 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/764d1eee-890d-4ffe-9eb0-6915907b6e18

Male, 76.9 years: Small cell carcinoma, NOS (ICD-O-3 8041/3); metastasis biopsied or resected from the ureter. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
